Somatic mutation profile of tumor specimen TCGA-E8-A437-01A (aliquot TCGA-E8-A437-01A-12D-A23U-08) from TCGA case TCGA-E8-A437, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 57.7 years (21,073 days).
Specimen TCGA-E8-A437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6769072b-2fb3-4bda-9301-e19dfd66deea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A437-10A (Blood Derived Normal), aliquot TCGA-E8-A437-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef00c42-fbe8-49bc-b898-ef1a7520c3fe

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALG13 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.015); catalogued as COSV52643858; called by muse, mutect2
- ALPK2 | c.1724T>C p.L575P | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV64496092; called by muse, mutect2, varscan2
- BEND2 | c.90A>T p.E30D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.043); catalogued as COSV66216912; called by muse, mutect2
- ITGAV | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53714735, COSV53717585; called by muse, mutect2, varscan2
- ITPA | c.526T>G p.S176A | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66263461; called by muse, mutect2, varscan2
- RSF1 | c.1430A>G p.D477G | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV57844489; called by muse, mutect2, varscan2
- SLC12A6 | c.689G>T p.C230F (on ENST00000354181 / NM_001365088.1; = p.C179F on NM_005135.2) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51630407; called by muse, mutect2, varscan2
- SYTL5 | c.424T>A p.S142T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as COSV52904595; called by muse, mutect2, varscan2
- ZNF573 | c.803A>T p.H268L (on ENST00000536220 / NM_001172692.1; = p.H210L on NM_152360.3) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59827249, COSV59827794; called by muse, mutect2, varscan2
- BRAF | c.1920G>A p.V640= (on ENST00000288602 / NM_001374244.1; = p.V600= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV56107175, COSV56109586; called by muse, mutect2, varscan2
- CLK1 | c.1353T>C p.F451= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV58435376; called by muse, mutect2, varscan2
- PDZRN4 | c.2235C>T p.C745= (on ENST00000402685 / NM_001164595.2; = p.C487= on NM_013377.4) | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as COSV100115602, COSV54213720; called by muse, mutect2, varscan2
- PGK2 | c.303C>T p.G101= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs549102825, COSV59163718; called by muse, mutect2, varscan2
- SLIT1 | c.1818C>T p.S606= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs527636768, COSV56586847, COSV56593311; called by muse, mutect2, varscan2
